Gene-level copy-number profile of tumor specimen ALCH-B1RS-TTP1-A from ALCHEMIST case ALCH-B1RS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.2 years (26,745 days).
Specimen ALCH-B1RS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 143973a4-4803-4872-b143-7d250d0af5e7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1RS-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/87f7f037-0f63-4d56-bafa-17448d15706e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 235; copy number 2: 57,845; copy number 3: 264; copy number 4: 5; copy number 5: 3.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:127,048,027–127,107,288, 1 gene: BIN1.
- chr9:136,796,338–136,810,042, 2 genes (within-gene range 0–5): CCDC183, AL355987.4.
- chr9:136,803,927–136,808,848, 1 gene (within-gene range 0–3): CCDC183-AS1.
- chr14:103,519,667–103,522,833, 1 gene: CKB.
- chr15:25,172,635–25,180,578, 5 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6.
- chr15:25,197,576–25,225,284, 16 genes (within-gene range 0–2): SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr16:89,873,570–89,920,973, 3 genes (within-gene range 0–1): TCF25, AC092143.3, MC1R.
- chr16:90,174,062–90,175,865, 1 gene (within-gene range 0–2): CICP25.
- chr17:78,261,349–78,278,492, 1 gene: LINC01993.
- chr20:63,861,212–63,864,293, 2 genes: AL118506.1, ABHD16B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:136,791,344–136,800,595, 2 genes, copy number 5 (within-gene range 0–5): TMEM141, AL355987.3.
- chr14:18,418,775–18,419,273, 1 gene, copy number 5: BNIP3P6.

Autosomal genes at a single copy (total copy number 1): 235. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
